Somatic mutation profile of tumor specimen TCGA-CR-6491-01A (aliquot TCGA-CR-6491-01A-11D-1870-08) from TCGA case TCGA-CR-6491, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.6 years (22,125 days).
Specimen TCGA-CR-6491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9d22c45-477c-45c1-9f45-6228765d9e85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6491-10A (Blood Derived Normal), aliquot TCGA-CR-6491-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd779378-2854-42a8-8b00-6decba8e8fbf

The open-access MAF lists 151 somatic variants for this specimen: 109 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 39, Nonsense Mutation 5, Frame Shift Del 4, Frame Shift Ins 4, Splice Region 4, Intron 3, Splice Site 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-2A>G p.X153_splice | Splice Site (SNP) | VAF 27/46 reads (59%) | hotspot (GDC flag); catalogued as CS127045, CS1414343, COSV58683256, COSV58703271, COSV58726067; called by muse, mutect2, varscan2
- TP53 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882004, COSV52701833, COSV52875518, COSV53198341; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATXN2 | c.2195C>A p.A732D (on ENST00000550104; = p.A572D on NM_002973.4) | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1245753983, COSV101112901; called by muse, mutect2
- BCL11A | c.1653C>G p.C551W (on ENST00000335712 / NM_001365609.1; = p.C585W on NM_018014.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100186404, COSV59633932; called by muse, mutect2, varscan2
- C8orf58 | c.919A>G p.N307D (on ENST00000289989 / NM_001013842.3; = p.N299D on NM_173686.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99254767; called by muse, mutect2, varscan2
- CCSER2 | c.2297A>G p.Y766C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as rs1218691901, COSV99825293; called by muse, mutect2, varscan2
- CEP152 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100359123; called by muse, mutect2, varscan2
- CERKL | c.1606G>A p.V536I (on ENST00000339098 / NM_001030311.2; = p.V510I on NM_201548.5) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.408); catalogued as COSV59207469; called by muse, mutect2, varscan2
- CHN1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV69298700; called by muse, mutect2
- COL22A1 | c.4802C>T p.P1601L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs974691796, COSV57340741; called by muse, mutect2, varscan2
- COL6A2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200387819; called by muse, mutect2, varscan2
- COL6A3 | c.159A>T p.E53D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99800986; called by muse, mutect2, varscan2
- COQ8B | c.1471A>T p.K491* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99425091; called by muse, mutect2, varscan2
- CORO2A | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100674115; called by muse, mutect2, varscan2
- CRABP2 | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100957577; called by muse, mutect2, varscan2
- CSH2 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1345269682, COSV100400331; called by muse, mutect2
- CSH2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1357628511, COSV100400332; called by muse, mutect2
- DNAH11 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs781183805, COSV100180593; called by muse, mutect2, varscan2
- DNAH9 | c.6367A>T p.K2123* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as COSV99307815; called by muse, mutect2, varscan2
- DSCAM | c.5816G>A p.R1939H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV68020286; called by muse, mutect2, varscan2
- EFNA5 | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322021; called by muse, mutect2
- EP400 | c.1023C>A p.N341K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV100202129; called by muse, mutect2, varscan2
- EPHA5 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56638220, COSV99900954; called by muse, mutect2, varscan2
- EPHX2 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746887626, COSV100994564; called by mutect2, varscan2
- ERICH3 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100445538, COSV58615805; called by muse, mutect2
- FLNB | c.4010G>T p.G1337V | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914589; called by muse, mutect2, varscan2
- FN1 | c.1715T>A p.I572N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118133; called by muse, mutect2, varscan2
- FNDC3A | c.1876G>C p.D626H (on ENST00000492622 / NM_001079673.2; = p.D570H on NM_014923.5) | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101256937; called by muse, mutect2
- GFPT2 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53811082, COSV99518040; called by muse, mutect2, varscan2
- GFPT2 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99518043; called by muse, mutect2, varscan2
- GLCCI1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.371); catalogued as rs763614660, COSV56205591; called by muse, mutect2
- GLT1D1 | c.69G>A p.R23= | Splice Region (SNP) | VAF 61/167 reads (37%) | catalogued as COSV99897465; called by muse, mutect2, varscan2
- GTF3C1 | c.5368C>T p.Q1790* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100649669; called by muse, mutect2, varscan2
- GULP1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100771121; called by muse, mutect2, varscan2
- H2AC16 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as rs771562270, COSV100511403, COSV58901597; called by muse, mutect2
- HASPIN | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99561487; called by muse, varscan2
- HDAC9 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101287300; called by muse, mutect2
- IFRD2 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100269800; called by muse, mutect2, varscan2
- IGKV1D-42 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748229933; called by muse, varscan2
- IGSF10 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as rs949258817, COSV99193618; called by muse, mutect2, varscan2
- IPMK | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as COSV100445791; called by muse, mutect2, varscan2
- KCNQ3 | c.1599A>T p.K533N | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV101196388; called by muse, mutect2, varscan2
- KIT | c.1881G>T p.P627= | Splice Region (SNP) | VAF 38/91 reads (42%) | catalogued as COSV55400572, COSV99853606, COSV99855214; called by muse, mutect2, varscan2
- KMT2C | c.8263G>C p.D2755H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100076043; called by muse, mutect2, varscan2
- LRRC4C | c.276A>T p.K92N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.283); catalogued as COSV99539528; called by muse, mutect2, varscan2
- MACF1 | c.20714C>A p.P6905Q (on ENST00000372915; = p.P4950Q on NM_012090.5) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99246516; called by muse, mutect2, varscan2
- MAP3K10 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99454803; called by muse, mutect2, varscan2
- MBD6 | c.961A>T p.S321C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100851809; called by muse, mutect2, varscan2
- MMP25 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202155408, COSV100339603; called by muse, mutect2, varscan2
- MSL2 | c.1343C>G p.P448R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99388066; called by muse, mutect2, varscan2
- MTHFD2 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs767060160, COSV51202218; called by muse, mutect2, varscan2
- MUC5B | c.3955C>T p.P1319S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs747790027, COSV101500706; called by muse, mutect2, varscan2
- MYO6 | c.3028C>T p.R1010W | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs148245729; called by muse, mutect2, varscan2
- NFIA | c.1514C>T p.S505F (on ENST00000403491 / NM_001134673.4; = p.I474= on NM_005595.5) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100783388; called by muse, mutect2
- NLGN1 | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100850079; called by muse, mutect2, varscan2
- NLRP14 | c.2782A>T p.S928C | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as COSV100205389; called by muse, mutect2, varscan2
- NOP2 | c.2418C>G p.N806K (on ENST00000322166 / NM_001258308.2; = p.N802K on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV100351177, COSV100351346; called by muse, mutect2, varscan2
- NOXO1 | c.325G>A p.A109T (on ENST00000397280 / NM_172168.3; = p.A103T on NM_144603.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.345); catalogued as COSV99937097; called by muse, mutect2, varscan2
- NUP210 | c.3751A>G p.T1251A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99596946; called by muse, mutect2, varscan2
- OAS1 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV99177269; called by muse, mutect2, varscan2
- OR1N2 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV101031463; called by muse, mutect2
- PBX3 | c.1008C>T p.S336= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as rs200644689; called by mutect2, varscan2
- PFAS | c.2905C>G p.R969G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as COSV100119121; called by muse, mutect2, varscan2
- PI16 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV101028808; called by muse, mutect2
- PKHD1L1 | c.7859G>T p.G2620V | Missense Mutation (SNP) | VAF 126/268 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1339418245, COSV65742455; called by muse, mutect2, varscan2
- PLSCR1 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV100678448, COSV61012867; called by muse, mutect2, varscan2
- POLR1E | c.340C>T p.P114S (on ENST00000377792 / NM_001282766.1; = p.P52S on NM_022490.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100905429; called by muse, mutect2
- PSMC6 | c.347T>A p.M116K (on ENST00000612399; = p.M102K on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV101471211; called by muse, mutect2, varscan2
- PTPRZ1 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101100763; called by muse, mutect2, varscan2
- QPCT | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753696536, COSV58120939; called by muse, mutect2, varscan2
- RAD51D | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs757467813, COSV99339056; called by muse, mutect2, varscan2
- RALGAPA1 | c.4318G>T p.A1440S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99355924; called by muse, mutect2, varscan2
- RC3H1 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV99281707; called by muse, mutect2, varscan2
- SATB2 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs777257792, COSV53484717; called by muse, mutect2, varscan2
- SIGLEC9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs147625837; called by muse, mutect2, varscan2
- SLC4A4 | c.3077G>T p.S1026I (on ENST00000264485 / NM_001098484.3; = p.S982I on NM_003759.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV99142029; called by mutect2, varscan2
- SLITRK5 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs201788229, COSV61522692, COSV61523859; called by muse, mutect2, varscan2
- SPAG6 | c.1346T>A p.L449H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100510457; called by muse, mutect2, varscan2
- SREK1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as COSV99398758; called by muse, mutect2
- SYNE1 | c.16436T>A p.L5479* (on ENST00000367255 / NM_182961.4; = p.L5408* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as rs746338402, COSV99576691; called by muse, mutect2, varscan2
- TES | c.921G>A p.L307= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100829398; called by muse, mutect2
- TLR6 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101126304; called by muse, mutect2, varscan2
- TRIP11 | c.3128C>G p.T1043S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.314); catalogued as COSV99971131; called by muse, mutect2, varscan2
- TRMT61B | c.699+2T>C p.X233_splice | Splice Site (SNP) | VAF 104/316 reads (33%) | catalogued as COSV100066788; called by muse, mutect2, varscan2
- TRMU | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1569082148, COSV51990006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.10125A>T p.K3375N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV100921708; called by muse, mutect2, varscan2
- UGT1A5 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100530928; called by muse, mutect2, varscan2
- UNC5C | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71657936; called by muse, mutect2, varscan2
- URGCP | c.379G>T p.A127S (on ENST00000453200 / NM_001077663.3; = p.A118S on NM_017920.4) | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV99787852; called by muse, mutect2, varscan2
- WAC | c.381+2T>G p.X127_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | catalogued as COSV100611177; called by muse, mutect2, varscan2
- ZBTB48 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100039836; called by muse, mutect2
- ZMYM3 | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100078344; called by muse, mutect2
- ZMYM3 | c.3379G>T p.G1127C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100078346; called by muse, mutect2
- ZNF440 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV100407721; called by muse, mutect2, varscan2
- ZNF530 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV100252739; called by muse, mutect2
- ZNF569 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100386328; called by muse, mutect2
- ANGEL1 | c.1673_1676dup p.F561Cfs*50 | Frame Shift Ins (INS) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- CRYBB3 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.181); called by muse, mutect2
- DAPK2 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); called by muse, mutect2
- ESYT1 | c.2407_2415dup p.Y803_E805dup | In Frame Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- FMNL2 | c.2940dup p.Y981Ifs*2 | Frame Shift Ins (INS) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.169del p.W57Gfs*13 | Frame Shift Del (DEL) | VAF 49/201 reads (24%) | called by mutect2, pindel, varscan2
- NAV2 | c.6114_6117del p.F2038Lfs*34 (on ENST00000396087 / NM_001244963.2; = p.F1979Lfs*34 on NM_145117.5) | Frame Shift Del (DEL) | VAF 62/196 reads (32%) | called by pindel, varscan2
- TFAP2A | c.94dup p.Q32Pfs*139 (on ENST00000482890; = p.Q24Pfs*139 on NM_001032280.3) | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- TMCO3 | c.592del p.I198* | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- TTI2 | c.882dup p.A295Cfs*46 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- XIRP1 | c.3407_3422del p.V1136Afs*8 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- ZFP37 | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ABCC10 | c.2002C>T p.L668= (on ENST00000372530 / NM_001198934.2; = p.L640= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV99767903; called by muse, mutect2, varscan2
- ACSM3 | c.135C>T p.S45= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99184790, COSV99184938; called by muse, mutect2, varscan2
- AGTR1 | c.51T>C p.D17= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100837158; called by muse, mutect2, varscan2
- ATP7B | c.1893G>A p.L631= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99666915; called by muse, mutect2, varscan2
- BCR | c.174C>T p.Y58= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs868551442, COSV100007001; called by muse, mutect2
- C4orf3 | c.120C>T p.P40= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV101208175; called by muse, mutect2, varscan2
- CDC123 | c.57A>T p.R19= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV99827174; called by muse, mutect2, varscan2
- CHST5 | c.171C>T p.A57= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs372652437; called by muse, mutect2, varscan2
- CLCNKA | c.1137C>T p.P379= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as rs374291415; called by muse, mutect2
- COPA | c.27C>T p.S9= | Silent (SNP) | VAF 13/307 reads (4%) | catalogued as COSV99616705; called by muse, mutect2
- COQ8B | c.1470C>T p.R490= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99425093; called by muse, mutect2, varscan2
- DEDD2 | c.285C>T p.R95= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs991158015, COSV100004590; called by muse, mutect2, varscan2
- DPYSL3 | c.1266C>A p.A422= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV58331226; called by muse, mutect2
- EIF4G2 | c.393G>T p.L131= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as rs1470022672, COSV101151106; called by muse, mutect2, varscan2
- ELP3 | c.321T>C p.N107= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV99834184; called by muse, mutect2, varscan2
- FANK1 | c.255G>A p.L85= | Silent (SNP) | VAF 10/218 reads (5%) | catalogued as COSV100904815; called by muse, mutect2
- FLNB | c.2823G>T p.P941= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV55895200, COSV99914579; called by muse, mutect2, varscan2
- GCK | c.834C>T p.D278= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs200071687, CM032916, CM097113, COSV60786685; ClinVar: benign; called by muse, mutect2, varscan2
- GPR153 | c.414C>T p.S138= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100928603; called by muse, mutect2, varscan2
- HEXIM1 | c.525G>A p.K175= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs775437378, COSV100203580; called by muse, mutect2, varscan2
- HPSE2 | c.730C>T p.L244= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs765943631, COSV100986199; called by muse, mutect2, varscan2
- IFNA6 | c.129A>G p.Q43= | Silent (SNP) | VAF 69/101 reads (68%) | catalogued as rs954761980, COSV101207030; called by muse, mutect2, varscan2
- IGKV1D-42 | c.258C>T p.G86= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, varscan2
- KCNQ5 | c.2340C>T p.V780= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs754891925, COSV100572966; called by muse, mutect2, varscan2
- LPCAT3 | c.1173T>A p.V391= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV99781286; called by muse, mutect2, varscan2
- MFN2 | c.1113G>A p.A371= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs766570486, COSV99337029; ClinVar: likely benign; called by muse, mutect2, varscan2
- RDH8 | c.318G>A p.V106= (on ENST00000651512; = p.V86= on NM_015725.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99408803; called by muse, mutect2, varscan2
- RPL23 | c.144G>A p.R48= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV99834770; called by muse, mutect2, varscan2
- SLC35G3 | c.78C>T p.R26= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99269172; called by muse, mutect2, varscan2
- SLC39A6 | c.6G>A p.A2= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs757540172, COSV52367681, COSV52369099; called by muse, mutect2, varscan2
- SLC6A13 | c.876C>T p.I292= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100570053; called by muse, mutect2, varscan2
- SLC6A19 | c.1383C>T p.L461= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs200312665, COSV100443740; called by muse, mutect2, varscan2
- SNX11 | c.393G>A p.S131= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.478C>T p.L160= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1177689595, COSV99538940; called by muse, mutect2, varscan2
- TMEM187 | c.690G>A p.K230= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as COSV100890190; called by muse, mutect2, varscan2
- TMTC4 | c.1275G>A p.L425= (on ENST00000376234 / NM_001350577.2; = p.L444= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100168864; called by muse, mutect2, varscan2
- UPF2 | c.2913T>C p.D971= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV100707432; called by muse, mutect2, varscan2
- URI1 | c.390C>T p.D130= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100369197; called by muse, mutect2, varscan2
- ZNF585A | c.915A>G p.K305= (on ENST00000292841 / NM_001288800.2; = p.K250= on NM_152655.3) | Silent (SNP) | VAF 99/253 reads (39%) | catalogued as COSV99493520; called by muse, mutect2, varscan2
- ACACA | c.339-14362A>T | Intron (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- KHDC4 | c.1266+1375dup | Intron (INS) | VAF 16/73 reads (22%) | catalogued as rs775014462; called by mutect2, pindel, varscan2
- NACA | c.70+4472A>G | Intron (SNP) | VAF 31/96 reads (32%) | catalogued as rs757375836, COSV100771603; called by muse, mutect2, varscan2
